Somatic mutation profile of tumor specimen TARGET-10-PARUCT-09A (aliquot TARGET-10-PARUCT-09A-01D) from TARGET case TARGET-10-PARUCT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.7 years (5,358 days).
Specimen TARGET-10-PARUCT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa4879d0-a812-40ac-aadc-1469265bf0ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUCT-10A (Blood Derived Normal), aliquot TARGET-10-PARUCT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c19d159e-a57c-4a93-b3aa-d8291b547994

The open-access MAF lists 41 somatic variants for this specimen: 18 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 12, Intron 8, Nonsense Mutation 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99867055; called by muse, mutect2, varscan2
- HIVEP3 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56013408; called by muse, mutect2
- IL1RAPL1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV56285655; called by muse, mutect2, varscan2
- MPPED1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV68837356; called by muse, mutect2
- MSC | c.63C>A p.Y21* | Nonsense Mutation (SNP) | VAF 25/44 reads (57%) | catalogued as COSV100335873; called by muse, mutect2, varscan2
- MSMO1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191326186; called by muse, mutect2, varscan2
- PLOD2 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776078472, COSV51464627; called by muse, mutect2, varscan2
- PLPP4 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV64827377; called by muse, mutect2, varscan2
- SYT1 | c.382T>A p.L128M | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV99693891; called by muse, mutect2
- ARHGEF12 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CDC5L | c.1646C>G p.S549* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- FLG2 | c.5081C>T p.T1694I | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); called by muse, mutect2
- NEFM | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- PRRT3 | c.2912C>A p.S971Y | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAMD8 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- TTN | c.88048G>A p.A29350T (on ENST00000591111; = p.A21926T on NM_003319.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF552 | c.1047G>C p.Q349H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZSCAN23 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ABLIM1 | c.768C>T p.C256= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs370541845; called by muse, mutect2, varscan2
- ACYP2 | c.69C>T p.F23= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.3522A>C p.T1174= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CEP170 | c.4272C>T p.F1424= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- FAM160A1 | c.591C>A p.I197= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- FAM209B | c.147A>G p.P49= | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- HIVEP3 | c.570C>G p.G190= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- HOPX | c.165G>A p.L55= (on ENST00000317745; = p.L73= on NM_032495.6) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100496993; called by muse, mutect2, varscan2
- LRRC30 | c.681G>A p.S227= | Silent (SNP) | VAF 64/132 reads (48%) | catalogued as rs368648942; called by muse, mutect2, varscan2
- MINAR1 | c.777C>T p.I259= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV59583222; called by muse, mutect2
- RYR3 | c.6532C>T p.L2178= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- TTN | c.27519C>A p.L9173= (on ENST00000591111; = p.L8246= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100613598; called by muse, mutect2
- AC068643.2 | n.593+3811G>C | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- BLCAP | c.*434C>G | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- CSRP3 | c.*67G>A | 3'UTR (SNP) | VAF 33/88 reads (38%) | catalogued as rs936525460; called by muse, mutect2, varscan2
- MORN1 | c.1036+1985G>A | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- NEURL4 | c.3864+60G>T | Intron (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- RBM4B | c.412+100C>T | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- TBC1D30 | c.644-2883G>A | Intron (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2, varscan2
- TEKT4 | c.499-596C>T | Intron (SNP) | VAF 31/70 reads (44%) | catalogued as rs1443641987; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331118 T>G | 5'Flank (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- U2AF1 | c.250-45T>C | Intron (SNP) | VAF 26/31 reads (84%) | called by muse, mutect2, varscan2
- ZNF85 | c.230-5934C>G | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
